Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A40S, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A40S-01A (Primary Tumor).

7/14/12

Spec. Taken

INTERPRETATION AND DIAGNOSIS:

1) LEFT INFERIOR PARATHYROID (EXCISION): PARATHYROID TISSUE (7 MG).

2) THYROID AND SOFT TISSUE (TOTAL THYROIDECTOMY AND LEVEL 6 LYMPH NODE):

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Right lobe, left lobe

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR SIZE:

Greatest dimension: 2.5 cm

FOCALITY:

Multifocal

LYMPH NODES:

All 12 lymph nodes are negative for tumor.

EXTENT OF INVASION (Edition AJCC):

PRIMARY TUMOR:

pT2: Tumor >2cm, but <=4cm, limited to thyroid

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: 1 mm

VENOUS/LYMPHATIC INVASION:

Absent

Additional Pathological Findings:

Twelve lymph nodes, negative for tumor

Source: NCI Genomic Data Commons file 4d48e405-f57b-4b97-adce-d969c5f3f846 (TCGA-ET-A40S.82520D7D-DA01-4884-BFD9-1396B05E0C5A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).